Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7866, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7866-01A (Primary Tumor).

[REDACTED]

INTERPRETATION AND DIAGNOSIS: [REDACTED]

RIGHT TONSIL MASS (EXCISION): HPV RELATED SQUAMOUS CELL CARCINOMA.
SEE NOTE.

NOTE: THE TUMOR IS STRONGLY IMMUNOREACTIVE FOR P16 AND POSITIVE FOR
HIGH RISK HPV BY IN SITU HYBRIDIZATION (PUNCTATE SIGNALS IN TUMOR
NUCLEI). [REDACTED] HAS SEEN THIS CASE.

[REDACTED]

*Electronic signature by which I attest that the above diagnosis is
based upon my personal examination of the slides (and / or other
material indicated in the diagnosis), and that I have reviewed and
approved this report.

=====

GROSS DESCRIPTION

PART #1: RIGHT TONSIL MASS [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh, labeled [REDACTED] and is
designated right tonsil mass. The specimen consists of 2 unoriented
of soft red-tan tissue, measuring 3.1 x 1.1 x 0.6 cm in aggregate.
The presumed cauterized resection margin is inked black. The larger
tissue piece is bisected and the specimen is entirely submitted.

SUMMARY OF SECTIONS:

1 - A - 3

1 - TOTAL - 3

=====

(End of Report) [REDACTED]

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

[REDACTED] FINAL DOCUMENT [REDACTED]

Source: NCI Genomic Data Commons file 7814d758-d902-4d47-b955-332471244718 (TCGA-BB-7866.EFC508EE-E176-4502-99E4-0CC774F7F9DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).